Gene-level copy-number profile of tumor specimen C3N-02769-02 from CPTAC case C3N-02769, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.9 years (19,701 days).
Specimen C3N-02769-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e99bcda3-f015-4a8f-a449-18448b384ee6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02769-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/75538543-297e-4fe4-9ea6-771529b09264

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 12,806; copy number 2: 40,474; copy number 3: 5,350; copy number 4: 198; copy number 9: 8; copy number 11: 1; copy number 12: 8; copy number 16: 1; copy number 24: 36; copy number 37: 3; copy number 38: 4; copy number 40: 4; copy number 41: 2.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–1): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 67 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,474,973–13,825,079, 8 genes, copy number 9: LRRC38, AL354712.1, BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2, PRDM2.
- chr7:54,752,250–56,163,533, 45 genes, copy number 12–24: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4.
- chr7:65,814,672–65,814,775, 1 gene, copy number 11: RNU6-912P.
- chr11:33,256,672–33,357,023, 1 gene, copy number 40: HIPK3.
- chr11:33,403,216–33,450,943, 2 genes, copy number 40: AL137161.1, AL133399.1.
- chr11:62,011,751–62,082,184, 3 genes, copy number 40–41: AP003733.1, LINC02733, AP003733.2.
- chr11:69,641,156–69,738,017, 4 genes, copy number 38: CCND1, LTO1, FGF19, DNAJB6P5.
- chr11:70,056,230–70,075,469, 3 genes, copy number 37: LINC02753, LINC02584, RNU6-1175P.

Autosomal genes at a single copy (total copy number 1): 9,952. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
